Gene-level copy-number profile of tumor specimen C3L-06338-03 from CPTAC case C3L-06338, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 59.3 years (21,650 days).
Specimen C3L-06338-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file c22d7402-7411-416b-8060-a6282bd19caa.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-06338-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,750 have no estimate.
https://portal.gdc.cancer.gov/files/e3c746e5-82a3-4f65-8911-bd564fce3cc8

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 638; copy number 1: 13,480; copy number 2: 29,167; copy number 3: 14,708; copy number 4: 720; copy number 5: 122; copy number 6: 38.

Homozygous deletions (total copy number 0; autosomes only): 126 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:75,521,803–75,522,012, 1 gene: SNRPCP10.
- chr3:75,542,149–75,542,929, 1 gene (within-gene range 0–2): RPS3AP15.
- chr4:4,117,925–4,150,421, 3 genes: AC116562.1, OR7E103P, UNC93B4.
- chr4:167,648,430–167,663,302, 2 genes: PHBP14, RN7SKP188.
- chr8:7,414,855–8,226,614, 56 genes: DEFB4B, HSPD1P3, DEFB103B, SPAG11B, DEFB104B, DEFB106B, DEFB105B, DEFB107B, PRR23D1, FAM90A6P, FAM90A7P, FAM90A21P, FAM90A22P, FAM90A23P, OR7E157P, AC134684.1, AC084121.1, OR7E154P, FAM90A14P, FAM90A18P, FAM90A16P, FAM90A8P, FAM90A17P, FAM90A19P, FAM90A9P, FAM90A10P, PRR23D2, PRR23D3P, DEFB107A, DEFB105A, DEFB106A, DEFB104A, SPAG11A, DEFB103A, HSPD1P2, DEFB4A, ZNF705B, DEFB108A, FAM66E, AC130365.1, USP17L8, USP17L3, DEFB109C, FAM90A11P, FAM90A24P, FAM90A12P, OR7E96P, AC105233.1, AC105233.4, AC105233.2, MIR548I3, RPS3AP31, SNRPCP17, ENPP7P1, FAM85B, AC068020.1.
- chr8:12,115,767–12,196,280, 9 genes: FAM66D, AC130366.1, USP17L7, USP17L2, DEFB109D, FAM90A2P, ALG1L11P, FAM86B1, AC145124.1.
- chr8:12,393,209–12,665,588, 10 genes (within-gene range 0–1): DEFB109A, AC087203.3, FAM90A25P, ALG1L12P, FAM86B2, ENPP7P6, AC068587.4, AC130352.1, RPS3AP34, AC068587.2.
- chr11:112,967–186,136, 5 genes (within-gene range 0–1): AC069287.1, CICP23, LINC01001, AC069287.3, RNU6-447P.
- chr13:57,204,379–57,204,799, 1 gene: MTCO2P3.
- chr15:20,803,505–21,058,440, 14 genes (within-gene range 0–1): AC012414.6, GRAMD4P5, AC012414.1, MIR3118-2, POTEB2, RNU6-749P, AC012414.5, AC037471.2, ZNF519P2, NF1P1, MIR5701-1, LINC01193, OR11J2P, OR11J5P.
- chr15:22,056,709–22,057,638, 1 gene (within-gene range 0–1): OR4H6P.
- chr17:36,165,681–36,241,806, 6 genes (within-gene range 0–2): TBC1D3B, AC243829.1, CCL3L3, CCL4L2, AC243829.3, AC243829.6.
- chr21:8,603,547–8,680,934, 2 genes: RPSAP68, CR381572.2.
- chr21:9,975,017–10,119,309, 2 genes: CR382285.1, CR382285.2.
- chr21:13,609,858–13,793,141, 13 genes: POTED, RNU6-286P, MIR3118-1, AL050303.2, GRAMD4P1, CXADRP1, AL050303.3, LONRF2P5, MIR8069-2, FEM1AP1, AL050303.1, TERF1P1, FAM207CP.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 160 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:27,663,471–27,715,732, 2 genes, copy number 5 (within-gene range 2–5): SLC4A1AP, LINC01460.
- chr7:56,805,336–62,275,678, 62 genes, copy number 5 (broad region; genes not listed).
- chr9:39,748,514–40,153,147, 13 genes, copy number 6: GLIDR, BX664615.1, FGF7P3, BX664615.2, RN7SL763P, SNORA70, CR769767.1, AL772307.1, RPL7AP49, AL773545.3, CDRT15P14, AL773545.1, AL773545.2.
- chr9:41,233,755–41,764,175, 21 genes, copy number 6: MIR4477A, RNA5SP530, AL845472.1, PTGER4P2-CDK2AP2P2, CDK2AP2P1, MYO5BP1, AL354718.2, CDRT15P6, AL354718.1, AL591926.3, SNORA70, RN7SL565P, AL591926.7, AL591926.6, AL591926.5, AL591926.2, FAM242F, Y_RNA, AL591926.1, AL591926.4, AL162731.1.
- chr9:62,686,912–63,059,217, 17 genes, copy number 5: ATP5F1AP7, SDR42E1P3, FKBP4P7, LINC01410, AL512625.3, RNA5SP283, AL512625.2, PTGER4P2, CDK2AP2P2, LERFS, MYO5BP2, ADGRF5P1, FGF7P8, AL512625.1, CNTNAP3P1, AL591379.2, BMS1P9.
- chr9:65,189,995–66,179,474, 27 genes, copy number 5: BMS1P12, AL512605.1, AL512605.2, IGKV1OR9-1, FOXD4L5, CBWD4P, Y_RNA, FRG1KP, CBWD5, FOXD4L4, IGKV1OR-3, BX284632.2, BX284632.1, BMS1P13, AC129778.1, AQP7P3, AL136317.2, AL136317.1, GXYLT1P4, AL136317.3, AL669942.2, AL669942.1, AL513478.4, SNX18P4, AL513478.1, ANKRD20A3P, RNU6-538P.
- chr20:32,005,671–32,355,734, 14 genes, copy number 5: AL031658.1, RNA5SP481, CCM2L, RNA5SP482, HCK, TM9SF4, AL049539.1, RSL24D1P6, TSPY26P, PLAGL2, POFUT1, MIR1825, KIF3B, AL121583.1.
- chr22:50,274,979–50,327,012, 4 genes, copy number 6 (within-gene range 3–6): PLXNB2, DENND6B, CR559946.1, CR559946.2.

Autosomal genes at a single copy (total copy number 1): 11,137. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
